Somatic mutation profile of tumor specimen BA2835D (aliquot aq-BA2835D) from BEATAML1.0 case 2214, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.1 years (27,426 days).
Specimen BA2835D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d027c50e-6506-43c1-b02c-95db7666b6ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2342D (Solid Tissue Normal), aliquot aq-BA2342D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ed5da4c-b132-4701-8553-c8033df04d7a

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 1, Splice Site 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1888del p.H630Tfs*73 | Frame Shift Del (DEL) | VAF 47/106 reads (44%) | catalogued as COSV60106946; called by mutect2, varscan2*
- USP9X | c.5863C>T p.R1955* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100198624; called by muse, mutect2
- HUNK | c.1173+1G>T p.X391_splice | Splice Site (SNP) | VAF 27/45 reads (60%) | called by muse, mutect2, varscan2
- DUSP18 | c.-77-1424C>T | Intron (SNP) | VAF 46/84 reads (55%) | called by muse, mutect2, varscan2
